Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JK, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JK-01A (Primary Tumor).

[page 1 of 2]
Requesting Doctor's Information:

ICD-6-3

Carcinoma, Adrenal Cortical 8870/2
Site: Adrenal Gland, cortex C74.2
Q40 1/25/13

SPECIMEN TYPE: Adrenal

CLINICAL NOTES:

En Bloc resection of Lt ACC + left kidney. Tumour thrombus in Lt renal vein.
Biopsy of tumour for genetics studies.

MACROSCOPIC:

The specimen consists of an en block resection of kidney, adrenal, renal vein and surrounding fat. The kidney is 120 x 80 x 60mm. Medial and superior to the kidney there is a mostly encapsulated tumour, 140 x 130 x 110mm. The tumour does not invade into the kidney parenchyma but is separated from the kidney by a narrow rim of fatty tissue. On sectioning, there is focal extension through the tumour capsule into the surrounding perinephritic fat, up to 13mm in depth. The tumour also invades directly into the adjacent renal vein forming a nodular tumour mass, 30 x 20 x 20mm in the vein lumen. The stapled resection margin of the renal vein appears abutted by the tumour mass. The cut surface of the tumour has a yellow/tan heterogenous appearance. It is variegated and haemorrhagic in areas. The tumour weighs 826g. The adjacent kidney appears normal on sectioning. At the hilum the artery 30mm in length, renal vein 70mm in length, and ureter 50mm in length are identified. The renal vein is involved as described previously. No lymph nodes are found despite careful examination of the peri-renal and peri-adrenal tissue.

Block 1: renal vein margin with tumour thrombus

Block 2: ureteric and renal artery margins

Blocks 3,4: tumour invading through capsule and extending into perinephritic fat

Blocks 5-7: further tumour invading directly into renal vein

Blocks 8-11: further tumour from various areas

Block 12: normal kidney

MICROSCOPIC:

The 826g 140 mm tumour is a high grade adrenal cortical carcinoma. The carcinoma displays 8 of the 9 Weiss criteria of malignancy. It is composed predominantly of pleomorphic cells with eosinophilic cytoplasm. There is extensive coagulative necrosis and some of the necrotic areas show dystrophic calcification. There is sinusoidal and venous invasion and, as described macroscopically, a 30 mm tumour thrombus is present in the renal vein. The mitotic rate is 4 mitoses per 50 hpf. Occasional atypical mitoses are present. The tumour is mostly well circumscribed but does show extra-adrenal spread. The tumour abuts the renal vein margin. It is separated from the soft tissue resection margins by intact tissue planes indicating that all other margins are

A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

[page 2 of 2]
Requesting Doctor's Information:

SPECIMEN TYPE: Adrenal

clear.

The adjacent non-neoplastic adrenal gland is normal. The kidney also shows no histological abnormality.

Immunohistochemistry is as follows:

IGF-2: Diffuse strong positive staining (with perinuclear dot-like positivity)

Glucocorticoid receptor: Positive (score 2+)

Ki-67 proliferative index: 5%

SUMMARY:

Left adrenal gland and kidney: Adrenal cortical carcinoma 140mm.

REPORTING PATHOLOGIST:

(Electronic Signature)

HIF 1A Discrepancy		

Page 2 of 2

Where 'Collected' Indicates Rec:

No collection details given. Received details entered as collection details.

P
A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

Source: NCI Genomic Data Commons file decff6a4-2979-4cf4-aa11-59e0036cb7a2 (TCGA-OR-A5JK.69DBF44F-F313-423E-8DD7-E3F80AE875B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).